Somatic mutation profile of tumor specimen 0DK96P from CCDI case PBBYAU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 1.3 years (471 days).
Specimen 0DK96P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b5a0173-c8ae-4ae4-9abe-85d868d5e284.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK96F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bbbff8f-ecc5-4e2a-875e-271fb71d5b12

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 154/1255 reads (12%) | catalogued as rs878855246, CM146272, COSV58623986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 58/2041 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
